Gene-level copy-number profile of tumor specimen TCGA-2G-AAH4-01A from TCGA case TCGA-2G-AAH4, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 34.2 years (12,481 days).
Specimen TCGA-2G-AAH4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.f626df31-0019-43b7-86b8-7ae8119ebe00.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AAH4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b56853cc-e0d3-46b1-881e-9ed3287f7fcf

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 431; copy number 2: 20,983; copy number 3: 32,496; copy number 4: 4,810; copy number 5: 25; copy number 7: 870; copy number 9: 3; copy number 10: 7; copy number 11: 2; copy number 15: 102; copy number 17: 90.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AAH4-01A-12D-A42X-01): tumor purity 0.85, ploidy 2.8, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,074 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:66,767–34,249,958, 850 genes, copy number 7 (broad region; genes not listed).
- chr12:67,658,991–72,670,758, 97 genes, copy number 10–17 (within-gene range 3–17) (broad region; genes not listed).
- chr17:15,014,805–17,035,057, 104 genes, copy number 11–15 (broad region; genes not listed).
- chr18:32,091,295–33,751,195, 23 genes, copy number 7–9: AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7, AC025887.2, WBP11P1, AC009835.1, AC025887.1, KLHL14, AC012123.1, AC012123.2, AC090371.2, CCDC178, AC090371.1, AC091198.1, ASXL3.

Autosomal genes at a single copy (total copy number 1): 431. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
